TCGA case TCGA-12-1597 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2b82e941-1b16-444e-af41-24dbc0a7e8b5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Dead; Days to death: 675 days (1.8 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 62.6 years (22,865 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Adjuvant; Days to treatment start: 0 days; Days to treatment end: 0 days; Number of cycles: 1; Treatment dose: 8 Wafer; Prescribed dose: 8; Prescribed dose units: Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 64 days; Days to treatment end: 88 days; Number of cycles: 1; Treatment dose: 1,550 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 123 days; Days to treatment end: 545 days (1.5 years); Number of cycles: 1; Treatment dose: 220 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 181 days; Days to treatment end: 308 days; Number of cycles: 3; Treatment dose: 2,880 mg; Prescribed dose: 125; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 313 days; Days to treatment end: 348 days; Number of cycles: 5; Treatment dose: 1,950 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 355 days; Days to treatment end: 427 days (1.2 years); Number of cycles: 2; Treatment dose: 1,500 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 6,000 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 63.1 years (23,045 days); Days to diagnosis: 180 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 180 (post initial treatment): Progression or recurrence: Yes; Days to progression: 180 days.
- Days to follow up: 427 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 675 days (1.8 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-1597-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-12-1597-01B-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0.
  Slide TCGA-12-1597-01B-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
- Sample TCGA-12-1597-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: CPT 11.
- Drug treatment 4, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: Gliadel Wafer.
- Drug treatment 5, Route of administrations: Route of administration: Intum.
- Drug treatment 6: Pharmaceutical therapy drug name: Ccnu.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 675 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 675 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 180 days.
